Somatic mutation profile of tumor specimen TCGA-B2-3923-01B (aliquot TCGA-B2-3923-01B-10D-A270-10) from TCGA case TCGA-B2-3923, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 59.7 years (21,793 days).
Specimen TCGA-B2-3923-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2b4f896-766b-4ad1-b6d4-97281edd3018.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B2-3923-10A (Blood Derived Normal), aliquot TCGA-B2-3923-10A-01D-1458-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/115e34df-b1b7-450e-90e9-5005d7392e5b

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 15, Silent 6, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM30 | c.97C>T p.H33Y | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.356); catalogued as COSV65560659; called by muse, mutect2, varscan2
- AHSA1 | c.941G>T p.R314L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.827); catalogued as COSV53631343, COSV53632886; called by muse, mutect2
- CPA5 | c.854G>A p.S285N | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs1554408687, COSV62569250; called by muse, mutect2
- DCAF12L2 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs1338664181, COSV63580237, COSV63583223; called by muse, mutect2, varscan2
- DOP1B | c.6083T>C p.M2028T | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs996130220, COSV67692664; called by muse, mutect2, varscan2
- GAN | c.968C>A p.S323* | Nonsense Mutation (SNP) | VAF 23/63 reads (37%) | catalogued as COSV73720808; called by muse, mutect2, varscan2
- KCNA5 | c.994G>A p.V332I | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.187); catalogued as COSV52907895; called by muse, varscan2
- PJA2 | c.1539T>G p.S513R | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63272221; called by muse, mutect2, varscan2
- SCUBE2 | c.1117A>T p.T373S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV58541557; called by muse, mutect2, varscan2
- TRPM4 | c.215C>A p.T72N | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs759027293, COSV53261327, COSV53264648; called by muse, mutect2, varscan2
- USP15 | c.441_443del p.V148del | In Frame Del (DEL) | VAF 26/102 reads (25%) | catalogued as rs1397041029; called by pindel, varscan2
- USP2 | c.875G>T p.R292I | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV99490024; called by muse, varscan2
- CAMSAP1 | c.4622G>A p.G1541D | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HEATR5B | c.3248G>A p.R1083Q | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNJ4 | c.1024G>A p.V342M | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PITPNM3 | c.1646G>A p.S549N | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.081); called by muse, varscan2
- SLIT3 | c.3479T>C p.V1160A | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, varscan2
- CCDC136 | c.1470C>T p.A490= | Silent (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2
- EML4 | c.2835C>T p.G945= | Silent (SNP) | VAF 3/20 reads (15%) | called by muse, varscan2
- HYAL4 | c.1185C>T p.P395= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as COSV56137995; called by muse, mutect2, varscan2
- TMEM184A | c.288C>T p.I96= | Silent (SNP) | VAF 3/23 reads (13%) | called by muse, varscan2
- TTC4 | c.1020G>T p.V340= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2, varscan2
- TULP4 | c.60G>A p.L20= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs1214464914; called by muse, varscan2
